Somatic mutation profile of tumor specimen ALCH-B0BB-TTP1-A (aliquot ALCH-B0BB-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0BB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.9 years (24,064 days).
Specimen ALCH-B0BB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac545687-0eb9-4a2c-80c7-5bcfc1dbcc3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0BB-NB1-A (Blood Derived Normal), aliquot ALCH-B0BB-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa1eb0a3-a5f0-4ab5-94b4-9107a76c309b

The open-access MAF lists 225 somatic variants for this specimen: 150 protein-altering or splice-affecting, 50 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 50, Nonsense Mutation 18, Intron 9, RNA 6, Splice Region 4, Frame Shift Del 4, 3'UTR 4, 5'UTR 3, 3'Flank 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 35/367 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC011005.1 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 50/772 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV71956005; called by muse, mutect2
- AC048338.2 | c.47T>G p.L16R | Missense Mutation (SNP) | VAF 39/304 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs1477779372; called by muse, mutect2, varscan2
- ACTA1 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.993); catalogued as COSV64203706; called by muse, mutect2
- AOC2 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 44/683 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs754555311, COSV53198529; called by muse, mutect2
- AP002512.3 | c.857del p.P286Lfs*17 | Frame Shift Del (DEL) | VAF 18/167 reads (11%) | catalogued as rs778062797; called by mutect2, pindel, varscan2
- C4BPB | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 19/279 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs757881039; called by muse, mutect2
- CACNA1E | c.3016C>A p.L1006I | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as COSV62382403; called by muse, mutect2, varscan2
- CCDC168 | c.234G>A p.T78= | Splice Region (SNP) | VAF 11/185 reads (6%) | catalogued as rs1193512102; called by muse, mutect2
- CLCA1 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52328086; called by muse, mutect2
- COL3A1 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 27/415 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.118); catalogued as rs530070719, COSV58584978; called by muse, mutect2
- CRNN | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 56/671 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs201228418; called by muse, mutect2
- DNMBP | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 35/403 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs1564744515, COSV60625872; called by muse, mutect2
- DPPA4 | c.679+6C>A | Splice Region (SNP) | VAF 45/508 reads (9%) | catalogued as COSV100169330; called by muse, mutect2
- DYTN | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs754984789; called by muse, mutect2, varscan2
- FOXP4 | c.1576G>T p.V526F (on ENST00000307972 / NM_001012426.1; = p.V513F on NM_138457.3) | Missense Mutation (SNP) | VAF 33/383 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100332807; called by muse, mutect2
- FRRS1 | c.1087G>T p.G363* | Nonsense Mutation (SNP) | VAF 36/494 reads (7%) | catalogued as COSV54922682, COSV54923944; called by muse, mutect2
- IGHV3-23 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 71/1073 reads (7%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as rs781814970; called by muse, mutect2
- LRP1B | c.2325G>T p.R775S | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as rs773725617; called by muse, mutect2
- LRP1B | c.1129C>A p.L377I | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV67183189; called by muse, varscan2
- LRRC37B | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 48/688 reads (7%) | catalogued as rs769507424; called by muse, mutect2
- MLC1 | c.389G>C p.G130A | Missense Mutation (SNP) | VAF 64/783 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61116115; called by muse, mutect2
- MRM3 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 48/363 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1221002035; called by muse, mutect2, varscan2
- OR2G6 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 59/332 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV58575223; called by muse, mutect2, varscan2
- OR2L13 | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 75/466 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63552744; called by muse, mutect2, varscan2
- OR52B6 | c.550C>A p.H184N | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs750394369; called by muse, mutect2, varscan2
- PARVG | c.125A>C p.K42T | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as rs762961993, COSV63562354; called by muse, mutect2
- PCDH9 | c.1394A>T p.N465I | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60535131; called by muse, mutect2
- PIK3C2A | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 12/239 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99791142; called by muse, mutect2
- PRG4 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 115/729 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as rs149006549; called by muse, mutect2, varscan2
- RHOBTB2 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.901); catalogued as rs1563292435, COSV52569840; called by muse, mutect2
- SLC28A1 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 56/714 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV54478167; called by muse, mutect2
- SNAP91 | c.2482G>T p.A828S | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs746752663, COSV52114288; called by muse, mutect2, varscan2
- TRERF1 | c.1108C>A p.P370T | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV61676639; called by muse, mutect2
- TRIM51GP | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 46/513 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs773401928; called by muse, mutect2
- VPS13C | c.10518G>T p.L3506F (on ENST00000644861 / NM_020821.3; = p.L3463F on NM_017684.5) | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV51192755; called by muse, mutect2
- VPS36 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 24/362 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs1409019088; called by muse, mutect2
- ZFR2 | c.2397C>A p.C799* | Nonsense Mutation (SNP) | VAF 14/195 reads (7%) | catalogued as rs1379732003, COSV53596041, COSV99507269; called by muse, mutect2
- ZFR2 | c.2023C>T p.R675C | Missense Mutation (SNP) | VAF 21/243 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs541626170, COSV53597171; called by muse, mutect2
- ZNF334 | c.608A>T p.Q203L | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV61618713; called by muse, varscan2
- ZNF677 | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV100447790; called by muse, mutect2, varscan2
- ZXDC | c.1939C>T p.R647* | Nonsense Mutation (SNP) | VAF 68/568 reads (12%) | catalogued as rs1209338334, COSV60446655; called by muse, mutect2, varscan2
- ADAMTS2 | c.1299C>A p.S433R | Missense Mutation (SNP) | VAF 27/335 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRE1 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 28/412 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.627); called by muse, mutect2
- AEBP1 | c.695C>T p.T232I | Missense Mutation (SNP) | VAF 46/454 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ANK2 | c.6493C>A p.H2165N | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.031); called by muse, mutect2
- ARHGAP44 | c.122A>T p.Q41L | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ARHGAP44 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ATM | c.6117A>T p.E2039D | Missense Mutation (SNP) | VAF 62/555 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ATP6V0C | c.416A>T p.E139V | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BBS10 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- BEGAIN | c.1004A>T p.D335V | Missense Mutation (SNP) | VAF 27/356 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2
- BMP1 | c.2108-7C>T | Splice Region (SNP) | VAF 30/502 reads (6%) | called by muse, mutect2
- CD109 | c.2704G>T p.D902Y | Missense Mutation (SNP) | VAF 42/382 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDCA5 | c.312G>T p.K104N | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2
- CDKL4 | c.853T>C p.Y285H | Missense Mutation (SNP) | VAF 12/239 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.248); called by muse, mutect2
- CDS2 | c.1313T>C p.L438P | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CHRNA7 | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 25/325 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COL21A1 | c.2283del p.A763Qfs*38 | Frame Shift Del (DEL) | VAF 35/215 reads (16%) | called by mutect2, pindel, varscan2
- COL6A3 | c.3341T>A p.F1114Y | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.114); called by muse, varscan2
- CUL3 | c.427G>T p.G143* | Nonsense Mutation (SNP) | VAF 13/178 reads (7%) | called by muse, mutect2
- CYP26C1 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DAAM2 | c.1898G>T p.R633L | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2
- DDHD1 | c.649G>T p.G217C (on ENST00000323669; = p.G414C on NM_030637.3) | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DICER1 | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- DISC1 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 62/493 reads (13%) | called by muse, mutect2, varscan2
- DMD | c.1597C>A p.L533I | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAJC5B | c.44C>A p.T15K | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DSP | c.2121C>G p.N707K | Missense Mutation (SNP) | VAF 30/349 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.07); called by muse, mutect2
- F13A1 | c.1949C>G p.T650R | Missense Mutation (SNP) | VAF 58/602 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.186); called by muse, mutect2
- FAT3 | c.1921A>C p.N641H | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- FYN | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 40/483 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- GOLGB1 | c.6370G>T p.E2124* | Nonsense Mutation (SNP) | VAF 21/142 reads (15%) | called by muse, mutect2, varscan2
- GP2 | c.1279G>T p.D427Y (on ENST00000381362 / NM_001007240.3; = p.D424Y on NM_001502.4) | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPR37 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 25/254 reads (10%) | called by muse, mutect2
- GRM5 | c.2020G>T p.A674S | Missense Mutation (SNP) | VAF 51/500 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GZF1 | c.1908T>A p.D636E | Missense Mutation (SNP) | VAF 44/505 reads (9%) | SIFT tolerated (0.91); PolyPhen benign (0.001); called by muse, mutect2
- HIVEP3 | c.5243G>T p.G1748V | Missense Mutation (SNP) | VAF 50/427 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IQSEC3 | c.1117G>T p.G373C (on ENST00000538872 / NM_001170738.2; = p.G70C on NM_015232.1) | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); called by muse, mutect2
- ITPR3 | c.4152G>T p.E1384D | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- KDM2B | c.3556C>A p.L1186I | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.65); called by muse, mutect2
- KLF15 | c.920A>T p.Q307L | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); called by muse, mutect2
- KLK2 | c.231del p.H78Tfs*26 | Frame Shift Del (DEL) | VAF 24/218 reads (11%) | called by mutect2, pindel, varscan2
- LOXHD1 | c.3357C>A p.Y1119* | Nonsense Mutation (SNP) | VAF 38/396 reads (10%) | called by muse, mutect2
- LRG1 | c.1010del p.G337Afs*18 | Frame Shift Del (DEL) | VAF 10/97 reads (10%) | called by mutect2, pindel, varscan2
- MARCHF4 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 36/512 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.776); called by muse, mutect2
- MCM9 | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.245); called by muse, mutect2
- MGAT4D | c.686G>A p.S229N | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MIA3 | c.2562G>T p.K854N | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MIDEAS | c.1916G>C p.R639P | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MKI67 | c.5084G>T p.R1695M | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- MKRN1 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 36/400 reads (9%) | called by muse, mutect2
- MRC1 | c.1639G>T p.E547* | Nonsense Mutation (SNP) | VAF 42/297 reads (14%) | called by muse, mutect2, varscan2
- MTF1 | c.532G>T p.G178C | Missense Mutation (SNP) | VAF 52/552 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MYLIP | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 45/505 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- NAV3 | c.6053A>T p.K2018I (on ENST00000397909 / NM_001024383.2; = p.K1996I on NM_014903.6) | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, varscan2
- NFATC2 | c.2317G>T p.A773S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0); called by mutect2, varscan2
- NR3C2 | c.1229G>A p.C410Y | Missense Mutation (SNP) | VAF 35/432 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NR4A1 | c.959A>G p.Q320R | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2B2 | c.170C>A p.T57N | Missense Mutation (SNP) | VAF 21/246 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2
- OR2J2 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.117); called by muse, mutect2
- PCDH17 | c.3288G>T p.M1096I | Missense Mutation (SNP) | VAF 38/387 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); called by muse, mutect2
- PCDH7 | c.3122C>G p.S1041* | Nonsense Mutation (SNP) | VAF 16/237 reads (7%) | called by muse, mutect2
- PCDHB10 | c.2267G>A p.C756Y | Missense Mutation (SNP) | VAF 38/519 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.95); called by muse, mutect2
- PCDHGA4 | c.2041G>T p.G681C | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHF14 | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.376); called by muse, mutect2
- PHF20 | c.1830G>T p.E610D | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2
- PLCB1 | c.1013G>C p.G338A | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PLXNB3 | c.4425C>G p.Y1475* | Nonsense Mutation (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2
- PM20D1 | c.953C>A p.P318Q | Missense Mutation (SNP) | VAF 24/331 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- PRB4 | c.626C>A p.A209E | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PREX1 | c.1308C>A p.S436R | Missense Mutation (SNP) | VAF 33/393 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.2); called by muse, mutect2
- PSTPIP1 | c.434A>T p.E145V | Missense Mutation (SNP) | VAF 17/237 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2
- RAB28 | c.307A>T p.N103Y | Missense Mutation (SNP) | VAF 34/267 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RANBP3 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 33/548 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- RBMS3 | c.1205A>G p.Q402R (on ENST00000383767 / NM_001003793.3; = p.Q386R on NM_014483.3) | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- RGPD4 | c.2936C>A p.T979N | Missense Mutation (SNP) | VAF 38/668 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- RIC8B | c.1179G>T p.R393S | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.285); called by muse, mutect2
- RMND5A | c.464T>C p.V155A | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RSPH14 | c.526G>T p.V176F | Missense Mutation (SNP) | VAF 64/676 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.024); called by muse, mutect2
- RTL1 | c.2152T>G p.F718V | Missense Mutation (SNP) | VAF 33/492 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2
- SCG2 | c.405T>A p.Y135* | Nonsense Mutation (SNP) | VAF 36/313 reads (12%) | called by muse, mutect2, varscan2
- SEC24A | c.2985G>A p.W995* | Nonsense Mutation (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- SHLD2 | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); called by mutect2, varscan2
- SLC18B1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- SLC23A1 | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- SLC36A2 | c.1180+8G>C | Splice Region (SNP) | VAF 36/582 reads (6%) | called by muse, mutect2
- STARD9 | c.1631G>T p.G544V | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SVOP | c.1208T>A p.M403K | Missense Mutation (SNP) | VAF 29/530 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- SYAP1 | c.316A>G p.K106E | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SYCE1L | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 26/295 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- SYCE3 | c.206G>C p.C69S | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SYT16 | c.939C>A p.S313R | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TGFBR3 | c.2229G>T p.Q743H | Missense Mutation (SNP) | VAF 54/826 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2
- THBS1 | c.2614G>C p.D872H | Missense Mutation (SNP) | VAF 45/422 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM106C | c.635A>C p.H212P | Missense Mutation (SNP) | VAF 63/724 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM80 | c.178A>T p.S60C (on ENST00000526170 / NM_001276274.1; = p.S122C on NM_174940.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/528 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TRIM10 | c.1355C>A p.P452H | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TRPV5 | c.2008G>T p.G670W | Missense Mutation (SNP) | VAF 55/642 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); called by muse, mutect2
- TTC12 | c.1153A>T p.R385* | Nonsense Mutation (SNP) | VAF 16/136 reads (12%) | called by muse, varscan2
- UGGT1 | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- WTAP | c.373A>T p.K125* | Nonsense Mutation (SNP) | VAF 12/302 reads (4%) | called by muse, mutect2
- ZBED3 | c.457C>A p.R153S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- ZFC3H1 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 46/548 reads (8%) | called by muse, mutect2
- ZNF208 | c.3122C>A p.P1041H | Missense Mutation (SNP) | VAF 30/321 reads (9%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.938); called by muse, mutect2
- ZNF655 | c.622A>C p.T208P | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF676 | c.142T>A p.F48I (on ENST00000650058; = p.F16I on NM_001001411.3) | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2
- ZNF793 | c.881A>G p.Q294R | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.866); called by muse, mutect2
- ZNF853 | c.538C>A p.Q180K | Missense Mutation (SNP) | VAF 38/488 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); called by muse, mutect2
- ZYG11B | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ANKS1A | c.2883G>T p.T961= | Silent (SNP) | VAF 23/271 reads (8%) | called by muse, mutect2
- ANO9 | c.309C>T p.H103= | Silent (SNP) | VAF 24/266 reads (9%) | catalogued as rs145003945, COSV60447976; called by muse, mutect2
- ANTXRL | c.1371C>T p.C457= | Silent (SNP) | VAF 89/1282 reads (7%) | called by muse, mutect2
- C1orf167 | c.1965G>A p.R655= | Silent (SNP) | VAF 38/381 reads (10%) | called by muse, mutect2
- CACNA1C | c.240G>A p.Q80= | Silent (SNP) | VAF 58/716 reads (8%) | called by muse, mutect2
- CAMK2B | c.1146C>A p.T382= | Silent (SNP) | VAF 61/691 reads (9%) | catalogued as rs779949267; called by muse, mutect2
- CCKBR | c.570C>T p.P190= | Silent (SNP) | VAF 24/373 reads (6%) | catalogued as COSV58098724, COSV58105175; called by muse, mutect2
- CLCNKA | c.636C>G p.V212= | Silent (SNP) | VAF 42/516 reads (8%) | called by muse, mutect2
- CMYA5 | c.11463C>A p.A3821= | Silent (SNP) | VAF 42/422 reads (10%) | called by muse, mutect2
- COL25A1 | c.519G>T p.G173= | Silent (SNP) | VAF 14/231 reads (6%) | called by muse, mutect2
- CP | c.2052G>A p.T684= | Silent (SNP) | VAF 38/416 reads (9%) | catalogued as rs775884510; called by muse, mutect2
- DAZAP1 | c.195G>C p.G65= | Silent (SNP) | VAF 28/368 reads (8%) | called by muse, mutect2
- DIP2A | c.687G>T p.T229= | Silent (SNP) | VAF 50/360 reads (14%) | catalogued as COSV100595211; called by muse, mutect2, varscan2
- EID2 | c.246G>T p.A82= | Silent (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2, varscan2
- EPS15L1 | c.1119C>G p.G373= | Silent (SNP) | VAF 48/401 reads (12%) | catalogued as COSV50174470; called by muse, mutect2, varscan2
- FATE1 | c.246G>T p.L82= | Silent (SNP) | VAF 34/384 reads (9%) | called by muse, mutect2
- GABRB2 | c.465A>T p.T155= | Silent (SNP) | VAF 16/151 reads (11%) | called by muse, mutect2, varscan2
- GATA3 | c.54G>T p.V18= | Silent (SNP) | VAF 62/667 reads (9%) | called by muse, mutect2
- IRGC | c.897T>A p.R299= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs1167394317; called by muse, mutect2, varscan2
- ITGAX | c.87C>A p.A29= | Silent (SNP) | VAF 22/229 reads (10%) | called by muse, mutect2, varscan2
- KCNA6 | c.459C>A p.S153= | Silent (SNP) | VAF 53/505 reads (10%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.162G>T p.G54= | Silent (SNP) | VAF 107/1117 reads (10%) | called by muse, mutect2
- KRT1 | c.642G>T p.L214= | Silent (SNP) | VAF 49/454 reads (11%) | called by muse, mutect2, varscan2
- LRRTM4 | c.234C>T p.S78= | Silent (SNP) | VAF 46/460 reads (10%) | catalogued as COSV69140451; called by muse, mutect2
- MAGEA11 | c.480A>G p.L160= | Silent (SNP) | VAF 62/652 reads (10%) | called by muse, mutect2
- MARCHF4 | c.969G>A p.L323= | Silent (SNP) | VAF 36/510 reads (7%) | called by muse, mutect2
- MSH2 | c.2787A>T p.R929= | Silent (SNP) | VAF 13/126 reads (10%) | called by muse, mutect2, varscan2
- MYH7 | c.1476C>T p.H492= | Silent (SNP) | VAF 59/816 reads (7%) | called by muse, mutect2
- MYLK | c.900C>G p.P300= | Silent (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- OR10A7 | c.702C>A p.R234= | Silent (SNP) | VAF 28/265 reads (11%) | called by muse, mutect2, varscan2
- OR1A2 | c.861C>T p.I287= | Silent (SNP) | VAF 18/232 reads (8%) | catalogued as COSV67936842; called by muse, mutect2
- PARP15 | c.1014T>C p.A338= (on ENST00000464300 / NM_001113523.3; = p.A104= on NM_152615.2) | Silent (SNP) | VAF 26/322 reads (8%) | called by muse, mutect2
- PCDHA4 | c.1902G>A p.T634= | Silent (SNP) | VAF 72/631 reads (11%) | catalogued as COSV100793181, COSV100793358; called by muse, mutect2, varscan2
- PEAK3 | c.69G>A p.T23= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as rs781519940, COSV59702521; called by muse, mutect2, varscan2
- PKD1 | c.5685C>T p.S1895= | Silent (SNP) | VAF 169/539 reads (31%) | catalogued as rs1427285494; called by muse, mutect2, varscan2
- PLEKHG1 | c.2658C>T p.R886= | Silent (SNP) | VAF 25/242 reads (10%) | called by muse, mutect2, varscan2
- PLXNA3 | c.5457C>T p.S1819= | Silent (SNP) | VAF 10/186 reads (5%) | catalogued as rs781950346; called by muse, mutect2
- PRSS58 | c.666C>A p.G222= | Silent (SNP) | VAF 22/256 reads (9%) | catalogued as COSV101616072; called by muse, mutect2
- PSG9 | c.894C>G p.P298= | Silent (SNP) | VAF 66/646 reads (10%) | called by muse, mutect2
- RAET1L | c.165G>A p.Q55= | Silent (SNP) | VAF 69/819 reads (8%) | catalogued as rs773778368; called by muse, mutect2, varscan2
- RNF13 | c.69C>T p.L23= | Silent (SNP) | VAF 22/352 reads (6%) | called by muse, mutect2
- SLC35E2B | c.894G>T p.L298= | Silent (SNP) | VAF 32/656 reads (5%) | catalogued as rs544200514, COSV99327549; called by muse, mutect2
- SP3 | c.1407A>G p.Q469= | Silent (SNP) | VAF 48/478 reads (10%) | catalogued as rs781204102; called by muse, mutect2, varscan2
- SYNE2 | c.420T>G p.L140= | Silent (SNP) | VAF 36/346 reads (10%) | called by muse, mutect2, varscan2
- TAS1R3 | c.921C>T p.D307= | Silent (SNP) | VAF 14/280 reads (5%) | called by muse, mutect2
- TENM4 | c.4524G>T p.G1508= | Silent (SNP) | VAF 64/416 reads (15%) | catalogued as COSV99569676; called by muse, mutect2, varscan2
- THSD7B | c.451C>A p.R151= | Silent (SNP) | VAF 61/527 reads (12%) | catalogued as COSV55675719, COSV99747403; called by muse, mutect2, varscan2
- TSHZ1 | c.417G>A p.S139= (on ENST00000580243 / NM_001308210.2; = p.S94= on NM_005786.6) | Silent (SNP) | VAF 41/331 reads (12%) | catalogued as rs761480832, COSV100433470; called by muse, mutect2, varscan2
- TUBA1B | c.456G>A p.L152= | Silent (SNP) | VAF 24/287 reads (8%) | called by muse, mutect2
- VAX2 | c.507G>T p.A169= | Silent (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- ACBD5 | chr10:27195504 T>A | 3'Flank (SNP) | VAF 20/161 reads (12%) | called by muse, mutect2, varscan2
- AGGF1 | c.-319G>T | 5'UTR (SNP) | VAF 40/308 reads (13%) | called by muse, mutect2
- C3P1 | n.3429C>T | RNA (SNP) | VAF 47/684 reads (7%) | called by muse, mutect2
- CASC15 | chr6:22147103 T>A | 5'Flank (SNP) | VAF 56/588 reads (10%) | called by muse, mutect2
- COL14A1 | c.5312-351C>A | Intron (SNP) | VAF 31/239 reads (13%) | called by muse, mutect2, varscan2
- DEFB117 | n.68G>T | RNA (SNP) | VAF 19/252 reads (8%) | called by muse, mutect2
- FARP2 | c.1411+134G>C | Intron (SNP) | VAF 8/118 reads (7%) | catalogued as rs1254275676; called by muse, mutect2
- H2BP2 | n.1061+584A>G | Intron (SNP) | VAF 39/770 reads (5%) | called by muse, mutect2
- HSPA7 | n.537G>T | RNA (SNP) | VAF 29/316 reads (9%) | catalogued as rs756521080; called by muse, mutect2
- IGKV1-12 | c.-11C>A | 5'UTR (SNP) | VAF 64/1873 reads (3%) | called by muse, mutect2
- LINC00905 | n.881C>A | RNA (SNP) | VAF 59/662 reads (9%) | called by muse, mutect2
- MAP4 | c.1999+3533G>T | Intron (SNP) | VAF 35/341 reads (10%) | catalogued as COSV99274900; called by muse, mutect2
- MIR6511B2 | chr16:15131110 T>G | 3'Flank (SNP) | VAF 28/406 reads (7%) | called by muse, mutect2
- MKRN9P | n.541T>A | RNA (SNP) | VAF 45/428 reads (11%) | called by muse, mutect2, varscan2
- MUC5B | c.16137-43T>C | Intron (SNP) | VAF 9/105 reads (9%) | called by muse, mutect2
- PNMA8A | c.*6G>C | 3'UTR (SNP) | VAF 17/234 reads (7%) | called by muse, mutect2
- POLQ | c.-59T>A | 5'UTR (SNP) | VAF 24/263 reads (9%) | called by muse, mutect2
- RDH10 | c.526-3533T>A | Intron (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- RNF170 | c.*1496T>C | 3'UTR (SNP) | VAF 19/258 reads (7%) | called by muse, mutect2
- RPH3A | c.1776-55G>A | Intron (SNP) | VAF 18/240 reads (8%) | catalogued as rs555662851; called by muse, mutect2
- STX3 | c.*56T>C | 3'UTR (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- TDRD7 | c.2302-11T>A | Intron (SNP) | VAF 48/369 reads (13%) | called by muse, mutect2, varscan2
- TMEM179 | c.*1G>T | 3'UTR (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- TPRX2P | n.469G>C | RNA (SNP) | VAF 16/157 reads (10%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+5292G>T | Intron (SNP) | VAF 38/384 reads (10%) | called by muse, mutect2
